CCDI case PBBRBK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/a0705672-cca6-41ae-99ba-7c18c4319217

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.7 years (3,538 days).

Biospecimens (3 samples)
- Sample 0DELJ7: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DEQWS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DEQWU: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
